Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NH-01A (Primary Tumor).

DIAGNOSIS:

A. Gallbladder, cholecystectomy: Chronic cholecystitis with Cholelithiasis and multiple (2) cholesterol polyps.

B. Liver, left lobe, partial hepatectomy: Hepatocellular carcinoma, grade 3 (of 4), is identified forming a dominant mass (11.5 x 7.5 x 5.5 cm) with multiple (5) satellite masses (ranging in size from 0.3 cm to 0.8 cm in greatest dimension). The tumor extensively infiltrates into the adjacent hepatic parenchyma and involves a major branch of the portal vein (tumor thrombus, 2.3 cm in length) and the middle hepatic vein (tumor thrombus, 4.0 cm in length). Major vascular and microvascular invasion are present. The liver parenchyma resection margin is negative for tumor (minimum tumor free margin, 0.1 cm). Multiple (5) regional lymph nodes are negative for tumor.

The background liver parenchyma shows mild steatosis without inflammation. Masson trichrome special stains shows slight periportal fibrosis. No PAS-positive cytoplasmic globules are noted.

ICD-O-3
Carcinoma, hepatocellular 8170/3
Site: Liver C22.0
JW12/24/12

JW 9/20/12

Source: NCI Genomic Data Commons file 59c0e275-01a7-43f1-8dad-ddee9c343a0b (TCGA-DD-A4NH.C9179EC7-2990-4581-B652-60289CC895F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).